Somatic mutation profile of tumor specimen TARGET-30-PATMPC-01A (aliquot TARGET-30-PATMPC-01A-01D) from TARGET case TARGET-30-PATMPC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 3.6 years (1,319 days).
Specimen TARGET-30-PATMPC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fcb9f7a-cd31-4d29-be44-db020c9e4936.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATMPC-10A (Blood Derived Normal), aliquot TARGET-30-PATMPC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5e5cd7d-b771-4607-9313-354b95381496

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRJ | c.2314A>G p.N772D | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs756647149, COSV69253024; called by muse, mutect2, varscan2
- RIPOR1 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50340936; called by muse, mutect2, varscan2
- ROR1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs1386277195; called by muse, mutect2
